Surgical pathology report (de-identified scan), TCGA case TCGA-85-8048, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8048-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Requisition [REDACTED]

[REDACTED]	Case ID	OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments
	[REDACTED]	[REDACTED]				

[page 2 of 2]
Formatted Path Report	Laterality/location		Date of excision
LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 2 x 3 x 2.5 cm Histologic type: Squamous cell carcinoma Histologic grade: Poorly differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	Left- lower		

Source: NCI Genomic Data Commons file 7b905300-0a06-475b-9240-53d9440625d8 (TCGA-85-8048.623E4187-FD10-4780-94D9-FEBF2957A922.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).